Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7722, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7722-01A (Primary Tumor).

[page 1 of 3]
TCGA Pathology Reports

Asterand Case ID	Open Clinica Subject ID	TCGA	Gross Description
		BR-7722	Stomach segment with the esophagus part. Stomach segment with the plate-like tumour, 3 cm in its largest dimension, infiltrates all layers of the stomach wall and diaphragm. Greater and lesser curvature lymph nodes are dense, hyperemic; esophageal margins are free of metastases.

[page 2 of 3]
Microscopic Description	Diagnosis Details	Formatted Path Report
Adenocarcinoma of the stomach, G3, all layers of the stomach wall invasion. Tumour invades the diaphragm, with the foci of perineural invasion. Surgical margins along the stomach -- discoupling and moderate dysplasia of glands, inflammatory infiltration, haemorrhages. Esophageal surgical margins are free of metastases. Fifteen lymph nodes were examined, five demonstrated metastases, others -- focal fibrosis. Omentum -- haemorrhages.	Tumor Features: Ulcerated, Tumor Extent: Adjacent structures, Venous Invasion: Absent, Margins: Absent, Treatment Effect:	STOMACH TISSUE CHECKLIST Specimen type: Total gastrectomy Tumor site: Stomach Tumor size: 3 x 0 x 0 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Diaphragm Lymph nodes: 5/15 positive for metastasis (Greater and lesser omentum 5/15) Lymphatic invasion: Present Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
Date of Procurement

Source: NCI Genomic Data Commons file 3da38bd9-4bcc-40bc-8798-e5e732c2ec36 (TCGA-BR-7722.D937C398-E733-474B-8376-8AFD4E53918B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).